Somatic mutation profile of tumor specimen TCGA-IR-A3LL-01A (aliquot TCGA-IR-A3LL-01A-11D-A20U-09) from TCGA case TCGA-IR-A3LL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 60.6 years (22,123 days).
Specimen TCGA-IR-A3LL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35b70d69-cde9-4e54-8121-207a99a549d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IR-A3LL-10A (Blood Derived Normal), aliquot TCGA-IR-A3LL-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/400ea322-72ca-41a6-bc77-8b8d9c5ece06

The open-access MAF lists 408 somatic variants for this specimen: 291 protein-altering or splice-affecting, 106 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 255, Silent 106, Nonsense Mutation 26, Splice Site 6, RNA 4, 3'UTR 3, 5'Flank 2, Splice Region 2, Intron 2, Nonstop Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OCRL | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853263, CM050304, COSV63980555; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2
- WDR45 | c.574C>T p.Q192* (on ENST00000376372 / NM_001029896.2; = p.Q193* on NM_007075.3) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs1557084077, COSV59876614; ClinVar: pathogenic; called by muse, varscan2
- AAMP | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV50307160; called by muse, mutect2, varscan2
- ABCA2 | c.2302-1G>A p.X768_splice (on ENST00000614293; = p.X738_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55799395; called by muse, mutect2, varscan2
- ACIN1 | c.1760C>G p.S587C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52974606; called by muse, mutect2, varscan2
- ACO1 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59378449; called by muse, mutect2, varscan2
- ACSBG1 | c.372C>G p.F124L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as COSV51904480; called by muse, mutect2, varscan2
- ADAD1 | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV56642465; called by muse, mutect2, varscan2
- ADAM10 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV53050211, COSV53053502; called by muse, mutect2, varscan2
- ADAM9 | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV101166144, COSV65959458; called by muse, mutect2, varscan2
- ADGRL2 | c.2352C>G p.F784L (on ENST00000370717 / NM_001366005.1; = p.F771L on NM_012302.4) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99589354; called by muse, mutect2, varscan2
- ADH1B | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59295736; called by muse, mutect2
- AEBP1 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.456); catalogued as rs1450087116, COSV56256419; called by muse, mutect2, varscan2
- AGTPBP1 | c.3481G>C p.E1161Q (on ENST00000357081 / NM_001330701.2; = p.E1121Q on NM_015239.2) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as COSV61269993; called by muse, mutect2, varscan2
- AKAP7 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV63505010; called by muse, mutect2, varscan2
- AKT1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as rs368797346; called by muse, mutect2, varscan2
- ANK3 | c.7921G>A p.A2641T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV55050025; called by muse, mutect2, varscan2
- ANKRD44 | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.765); catalogued as COSV56551658; called by muse, mutect2, varscan2
- ANO4 | c.2092G>A p.D698N (on ENST00000392977 / NM_001286615.2; = p.D663N on NM_178826.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54589968; called by muse, mutect2, varscan2
- ANO9 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV60448833; called by muse, mutect2, varscan2
- ART4 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as rs1355091711, COSV57451453; called by muse, mutect2, varscan2
- ARV1 | c.504G>T p.M168I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100048552, COSV59617387; called by muse, mutect2, varscan2
- ASTN1 | c.3166G>C p.D1056H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV62494018; called by muse, mutect2, varscan2
- ATAD1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV57756255; called by muse, mutect2, varscan2
- ATAD2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54878995; called by muse, mutect2, varscan2
- ATM | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1334793787, COSV53734573; called by muse, mutect2, varscan2
- ATP5IF1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55281153; called by muse, mutect2, varscan2
- ATP6V1A | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56361487; called by muse, mutect2, varscan2
- BAAT | c.1140G>C p.L380F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV52287911; called by muse, mutect2, varscan2
- BMP4 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55415221, COSV55415481, COSV99816684; called by muse, mutect2, varscan2
- BTN3A3 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs140844974; called by muse, mutect2, varscan2
- CACNA1H | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs773757935, COSV61986618; called by muse, mutect2
- CALB2 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.222); catalogued as COSV56938660; called by muse, mutect2, varscan2
- CASP8 | c.1393C>T p.Q465* (on ENST00000432109 / NM_033355.3; = p.Q482* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV51844901; called by muse, mutect2, varscan2
- CATSPER4 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV58792665; called by muse, mutect2, varscan2
- CATSPERD | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs766938408, COSV58464752; called by muse, mutect2, varscan2
- CCDC58 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV52246643, COSV52247457; called by muse, mutect2, varscan2
- CCDC9 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV55720187; called by muse, mutect2, varscan2
- CD58 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65664683; called by muse, mutect2, varscan2
- CDC42EP4 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100231786, COSV59962371; called by muse, mutect2, varscan2
- CDH10 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.506); catalogued as COSV52575025; called by muse, mutect2, varscan2
- CECR2 | c.751G>C p.E251Q (on ENST00000342247 / NM_001290047.2; = p.E88Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV52838383; called by muse, mutect2, varscan2
- CENPE | c.4219G>T p.E1407* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as rs1440432920, COSV54378617; called by muse, mutect2, varscan2
- CENPT | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54648737; called by muse, mutect2, varscan2
- CEP128 | c.3122C>T p.S1041L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs767861364, COSV55367504, COSV55371900; called by muse, mutect2, varscan2
- CEP162 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV57618626; called by muse, mutect2, varscan2
- CFAP57 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs779198565, COSV52539599, COSV52540187; called by muse, mutect2, varscan2
- CFDP1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755077989, COSV99382698; called by muse, mutect2, varscan2
- CLCC1 | c.812C>A p.S271* (on ENST00000356970 / NM_001377464.1; = p.S221* on NM_015127.5) | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV56762660; called by muse, mutect2, varscan2
- CLEC14A | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60562119; called by muse, mutect2, varscan2
- CLTC | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV52246101; called by muse, mutect2, varscan2
- CNTNAP2 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV62159241; called by muse, mutect2, varscan2
- COA7 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV65299295; called by muse, varscan2
- COL15A1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV66642760; called by muse, mutect2, varscan2
- COL17A1 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs373205740; called by muse, mutect2, varscan2
- CRACR2A | c.1138C>G p.P380A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52911421; called by muse, mutect2, varscan2
- CREB5 | c.806C>T p.T269M (on ENST00000357727 / NM_182898.4; = p.T262M on NM_004904.3) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.446); catalogued as rs565546192, COSV63218686, COSV63228136; called by muse, mutect2, varscan2
- CSH1 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60241961; called by muse, mutect2, varscan2
- CSMD3 | c.9127G>A p.G3043R (on ENST00000297405 / NM_001363185.1; = p.G2874R on NM_052900.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs138442191; called by muse, mutect2, varscan2
- CSPP1 | c.3732G>C p.Q1244H (on ENST00000676605; = p.Q1203H on NM_024790.6) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV51581887; called by muse, mutect2
- DCANP1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV72345731, COSV72345830; called by muse, mutect2, varscan2
- DCC | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1208033056, COSV71429111; called by muse, mutect2, varscan2
- DENND2A | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV52049167, COSV52056219; called by muse, mutect2, varscan2
- DHRS4 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.063); catalogued as rs200717541, COSV100365788, COSV100365894; called by muse, mutect2, varscan2
- DHX58 | c.1752C>G p.F584L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52425031; called by muse, mutect2, varscan2
- DMD | c.8179G>A p.D2727N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV58900207, COSV58902431; called by muse, mutect2
- DNAJA1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV58309986; called by muse, mutect2, varscan2
- DUS3L | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs758799429, COSV57831522; called by muse, mutect2
- DYRK1A | c.804G>C p.Q268H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58293100; called by muse, mutect2, varscan2
- DZIP1L | c.2140C>G p.Q714E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100551386, COSV59523777; called by muse, mutect2, varscan2
- EDN2 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101006343; called by muse, mutect2
- EIF4A1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51510339, COSV51510627; called by muse, mutect2, varscan2
- EIF4A2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV56216288; called by muse, varscan2
- EMC1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs371524055, COSV64345489; called by muse, mutect2, varscan2
- ENKD1 | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778432021, COSV54666608, COSV54666814; called by muse, mutect2, varscan2
- EOGT | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV55150010, COSV55152781; called by muse, mutect2, varscan2
- EPHB3 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV57805007; called by muse, mutect2, varscan2
- EPS15 | c.1760C>G p.S587C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as COSV65541107; called by muse, mutect2, varscan2
- EPS15L1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV50167778; called by muse, mutect2, varscan2
- ERCC6L | c.1170C>G p.I390M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57819924; called by muse, mutect2, varscan2
- ESRP1 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64408569; called by muse, mutect2, varscan2
- ESYT3 | c.2403G>C p.R801S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV67440549; called by muse, mutect2, varscan2
- ETHE1 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52668615; called by muse, mutect2, varscan2
- EVC | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146232611; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EVC2 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.514); catalogued as rs1023896680, COSV60390158; called by muse, mutect2
- FAM118B | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1391924892, COSV64156827; called by muse, mutect2, varscan2
- FAM135B | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV52712421; called by muse, mutect2, varscan2
- FAM155A | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV65554804, COSV65583515; called by muse, mutect2, varscan2
- FAM166B | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV63428102; called by muse, mutect2, varscan2
- FAM189A2 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV57384098; called by muse, mutect2, varscan2
- FAM199X | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV101534165, COSV72419875; called by muse, mutect2, varscan2
- FAM81B | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV51981718; called by muse, mutect2, varscan2
- FBXL19 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs780434451, COSV57941538; called by muse, mutect2, varscan2
- FBXL20 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52897487; called by muse, mutect2, varscan2
- FBXO46 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.246); catalogued as COSV58348139; called by muse, mutect2, varscan2
- FHOD1 | c.3148C>A p.H1050N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV50759503; called by muse, varscan2
- FHOD1 | c.3065C>G p.S1022* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs990689517, COSV50759518; called by muse, varscan2
- FLG2 | c.2524C>T p.Q842* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as rs755667655, COSV66167421; called by muse, mutect2, varscan2
- FLT1 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56722657; called by muse, mutect2, varscan2
- FMOD | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV61609821, COSV61610510; called by muse, mutect2, varscan2
- FRAS1 | c.4654G>A p.E1552K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1358301764, COSV53598982; called by muse, mutect2, varscan2
- FSTL5 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV60178930, COSV60186532; called by muse, mutect2, varscan2
- GBF1 | c.3055C>T p.R1019C (on ENST00000369983 / NM_001377137.1; = p.R1018C on NM_004193.3) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1378917670, COSV64143772; called by muse, mutect2, varscan2
- GCLM | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV64686819; called by muse, mutect2, varscan2
- GLG1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.948); catalogued as rs1461879679, COSV52665146, COSV52673505; called by muse, mutect2, varscan2
- GNA15 | c.927G>C p.K309N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); catalogued as COSV53585581; called by muse, mutect2, varscan2
- GRAMD1B | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs369825461, COSV59202120; called by muse, mutect2, varscan2
- GRID2 | c.1068C>G p.I356M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.883); catalogued as COSV56187037; called by muse, mutect2, varscan2
- GSTO1 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV63846548; called by muse, mutect2, varscan2
- GTF2A2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as COSV51114967; called by muse, mutect2, varscan2
- GTF2F1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs148016023; called by muse, mutect2, varscan2
- H2BC7 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV61911735, COSV61912284; called by muse, mutect2, varscan2
- HEATR5A | c.4432C>T p.P1478S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV66339321; called by mutect2, varscan2
- HIP1 | c.228C>G p.F76L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782794159, COSV61184474; called by muse, mutect2, varscan2
- HLA-B | c.896-1G>A p.X299_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV69520575, COSV69520821; called by muse, mutect2, varscan2
- HMCN1 | c.6467G>C p.R2156T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54887457; called by muse, mutect2, varscan2
- HOMER3 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV55355358; called by muse, mutect2, varscan2
- HSD17B11 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64154081; called by muse, mutect2, varscan2
- HSPG2 | c.9535G>A p.D3179N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV65932925; called by muse, mutect2, varscan2
- IDO2 | c.634C>T p.Q212* (on ENST00000389060; = p.Q225* on NM_194294.2) | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV58424570; called by muse, mutect2, varscan2
- INA | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV63975770; called by muse, mutect2, varscan2
- IPO9 | c.2084C>G p.P695R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64233246; called by muse, mutect2, varscan2
- IQGAP1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51582982; called by muse, mutect2, varscan2
- ITGB1 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56480263; called by muse, mutect2
- ITPKC | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV54573921; called by muse, mutect2, varscan2
- ITSN2 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV61945094; called by muse, mutect2, varscan2
- JMJD1C | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV67859662; called by muse, mutect2, varscan2
- JMJD1C | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV67859668; called by muse, mutect2
- KCNK2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as rs766967584, COSV101222263, COSV67204276, COSV67204289; called by muse, mutect2, varscan2
- KDM2A | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1565416374, COSV67083236; called by muse, mutect2
- KIF26B | c.2390G>A p.R797K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63639121; called by muse, mutect2, varscan2
- KITLG | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV57200657; called by muse, varscan2
- KLF5 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66613937, COSV66614326; called by muse, mutect2, varscan2
- KMT2D | c.7009C>G p.Q2337E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56423351, COSV99986539; called by muse, varscan2
- KMT2D | c.6935C>G p.S2312* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV56410740, COSV56412606; called by muse, varscan2
- KMT2D | c.6202C>T p.R2068W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317305838, COSV56423387; called by muse, mutect2, varscan2
- KMT2D | c.4879G>A p.E1627K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.15); catalogued as COSV56423405; called by muse, mutect2, varscan2
- KMT2D | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV56423445, COSV56476847; called by muse, varscan2
- KMT2D | c.4033G>C p.D1345H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV56423462; called by muse, varscan2
- KMT2D | c.4027G>A p.D1343N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.867); catalogued as COSV56423483; called by muse, varscan2
- KMT5A | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1160049862, COSV57862584; called by muse, varscan2
- KRTAP13-3 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV61878527, COSV61878844; called by muse, mutect2, varscan2
- LCA5L | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV55744489; called by muse, varscan2
- LCA5L | c.1841C>G p.S614* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55744511; called by muse, varscan2
- LONP1 | c.1962G>C p.E654D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61501707; called by muse, mutect2, varscan2
- LRPPRC | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV53236131, COSV99581737; called by muse, mutect2, varscan2
- MAN1B1 | c.2007C>G p.F669L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV65371131; called by muse, mutect2, varscan2
- MBOAT7 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs759456879, COSV55474908, COSV55475460; called by muse, mutect2, varscan2
- MDN1 | c.5583G>C p.K1861N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV65519291; called by muse, mutect2, varscan2
- MEI1 | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.154); catalogued as COSV55901828; called by muse, mutect2, varscan2
- MGRN1 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV52149572, COSV99273956; called by muse, mutect2, varscan2
- MPIG6B | c.725G>C p.*242Sext*11 | Nonstop Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV101008104; called by muse, mutect2, varscan2
- MROH6 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs781182992, COSV52783576; called by muse, mutect2, varscan2
- MSLNL | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.401); catalogued as COSV53500599; called by muse, mutect2
- MTOR | c.7576G>A p.E2526K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV63869524, COSV63874394; called by muse, mutect2, varscan2
- MUTYH | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs781163298, COSV100588077, COSV58343816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MX2 | c.1273-1G>A p.X425_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58095813; called by muse, mutect2, varscan2
- MXRA5 | c.6860C>T p.S2287F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs749710230, COSV54229625; called by muse, mutect2, varscan2
- MYH15 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1343488441, COSV56306929; called by muse, mutect2, varscan2
- MYH7B | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.08); catalogued as COSV53417891; called by muse, mutect2, varscan2
- MYL5 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs1275846445, COSV58519859, COSV58520301; called by muse, mutect2, varscan2
- MYO7B | c.4715C>T p.S1572L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as rs373498646, COSV67345990; called by muse, mutect2, varscan2
- NBPF1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV101236472, COSV101236737; called by muse, mutect2, varscan2
- NCOA5 | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV51642921, COSV51643435; called by muse, mutect2, varscan2
- NCOR2 | c.6094G>C p.E2032Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.917); catalogued as COSV62295708; called by muse, mutect2, varscan2
- NDEL1 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.06); catalogued as COSV55325846; called by muse, mutect2, varscan2
- NECAB2 | c.1038G>C p.K346N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.911); catalogued as COSV59419856; called by muse, mutect2, varscan2
- NF1 | c.5893G>A p.D1965N (on ENST00000358273 / NM_001042492.3; = p.D1944N on NM_000267.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.358); catalogued as COSV62197611; called by muse, mutect2, varscan2
- NFU1 | c.516G>A p.M172I (on ENST00000410022 / NM_001002755.4; = p.M148I on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV58005992; called by muse, mutect2, varscan2
- NIBAN3 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53108143; called by muse, mutect2, varscan2
- NIPBL | c.7318T>A p.Y2440N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM042524, COSV56947079; called by muse, mutect2, varscan2
- NPAS2 | c.1288C>G p.P430A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV59556634; called by muse, mutect2, varscan2
- NR2F2 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV67683325; called by muse, mutect2
- NSMAF | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV50685127; called by muse, mutect2, varscan2
- NTMT1 | c.159G>C p.L53F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV52964659; called by muse, mutect2, varscan2
- NTPCR | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64052300; called by muse, mutect2, varscan2
- NXN | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV61094031; called by muse, mutect2, varscan2
- OGA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as COSV63381240; called by muse, mutect2, varscan2
- OOEP | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64859079; called by muse, mutect2, varscan2
- OR13C2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73377674; called by muse, mutect2, varscan2
- OR52R1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV61887889; called by muse, mutect2, varscan2
- OSBPL5 | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55140592; called by muse, varscan2
- OVCH1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs777307001, COSV58961109; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.526G>A p.E176K (on ENST00000259318 / NM_001136562.3; = p.E407K on NM_007203.5) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs146014470; called by muse, mutect2, varscan2
- PCGF6 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV61494662; called by muse, mutect2, varscan2
- PDILT | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs1301808424, COSV56700613, COSV56700781; called by muse, mutect2, varscan2
- PLEKHA8 | c.796+1G>C p.X266_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as COSV51649654; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV57963777; called by muse, mutect2, varscan2
- POGZ | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV55033783, COSV55037083; called by muse, mutect2, varscan2
- POLD1 | c.176A>T p.Q59L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV101486876; called by muse, mutect2
- PPP2R5E | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV61741044; called by muse, mutect2, varscan2
- PPP5C | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs749045957, COSV50139485; called by muse, mutect2, varscan2
- PRKCA | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs140466753; called by muse, mutect2, varscan2
- PRRC2C | c.5441C>T p.S1814L (on ENST00000367742; = p.S1812L on NM_015172.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100145319, COSV58903667; called by muse, mutect2, varscan2
- PSD | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs1276986579, COSV50043227; called by muse, mutect2, varscan2
- PSG4 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1299578080, COSV54934405; called by muse, mutect2, varscan2
- PUM2 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV57579007; called by muse, mutect2, varscan2
- PUM3 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV67396038; called by muse, mutect2, varscan2
- RAB6C | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV69339720; called by mutect2, varscan2
- RASGRF1 | c.879C>T p.S293= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as rs1396911876, COSV69177680; called by mutect2, varscan2
- RBL2 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV50874271; called by muse, mutect2, varscan2
- RNF145 | c.846C>G p.F282L (on ENST00000424310 / NM_001199383.2; = p.F310L on NM_144726.2) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV50865190; called by muse, mutect2, varscan2
- RNF220 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs539612817, COSV62405647; called by muse, mutect2, varscan2
- RNF5 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV61247261; called by muse, mutect2, varscan2
- ROS1 | c.5713G>C p.E1905Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63853244, COSV63860799; called by muse, mutect2, varscan2
- RPA1 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV54608378; called by muse, mutect2, varscan2
- RPL29 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as rs779424227, COSV53685745; called by muse, mutect2, varscan2
- RPL7A | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100034606; called by muse, mutect2, varscan2
- RSF1 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57837953; called by muse, mutect2, varscan2
- RYR1 | c.7121C>G p.S2374* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV62093137; called by muse, mutect2, varscan2
- SCG2 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV59539446; called by muse, mutect2, varscan2
- SDK1 | c.5747C>G p.S1916C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67361383; called by muse, mutect2, varscan2
- SERPINB11 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV66956627; called by muse, varscan2
- SERPINB11 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66956630; called by muse, varscan2
- SERPINB3 | c.613-1G>C p.X205_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52190439, COSV52191013; called by muse, varscan2
- SETDB1 | c.493C>G p.Q165E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); catalogued as COSV54979490; called by muse, mutect2, varscan2
- SFMBT1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV56252807; called by muse, mutect2, varscan2
- SGK3 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61894102; called by muse, varscan2
- SGK3 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV61894040; called by muse, varscan2
- SHARPIN | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs925928246, COSV59644097; called by muse, mutect2
- SHC2 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs1037127731, COSV52744719; called by muse, mutect2, varscan2
- SI | c.2704C>G p.H902D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100015064, COSV52271342; called by muse, mutect2, varscan2
- SIPA1L1 | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV62169248; called by muse, mutect2, varscan2
- SLC25A40 | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV62019522; called by muse, mutect2, varscan2
- SMARCC2 | c.3010C>G p.P1004A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.956); catalogued as COSV53237859, COSV99519169; called by muse, varscan2
- SMARCC2 | c.2908C>T p.Q970* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53237874, COSV99519674; called by muse, varscan2
- SNRNP200 | c.6388G>C p.E2130Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55530489; called by muse, mutect2, varscan2
- SORBS2 | c.103G>A p.D35N (on ENST00000284776 / NM_021069.5; = p.D81N on NM_003603.6) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV52995067; called by muse, mutect2, varscan2
- SPAG17 | c.5935G>C p.E1979Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV60455747; called by muse, mutect2, varscan2
- SPEF2 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61546087; called by muse, mutect2, varscan2
- SPINK5 | c.3070C>G p.P1024A | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99806805; called by muse, mutect2
- SRL | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV68423059; called by muse, mutect2, varscan2
- STARD10 | c.240G>C p.E80D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV58324893; called by muse, mutect2, varscan2
- SYNGAP1 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.775); catalogued as COSV53379519; called by muse, mutect2, varscan2
- TAF1L | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.953); catalogued as COSV54259812; called by muse, mutect2, varscan2
- TANGO2 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV59293176; called by muse, mutect2, varscan2
- TATDN1 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV52674560; called by muse, mutect2, varscan2
- TBC1D26 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as rs780878405, COSV68609029; called by muse, mutect2, varscan2
- TECPR1 | c.2826G>C p.E942D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.076); catalogued as COSV65782918; called by muse, mutect2, varscan2
- TEK | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV66228342; called by muse, mutect2, varscan2
- TEP1 | c.6406G>C p.E2136Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs767674334, COSV52990113; called by muse, mutect2
- THAP12 | c.1423T>C p.S475P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV52610017; called by muse, mutect2, varscan2
- THG1L | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.332); catalogued as COSV99180246; called by muse, mutect2
- TLR7 | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66123865; called by muse, mutect2, varscan2
- TMEFF2 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55830044; called by muse, mutect2, varscan2
- TNC | c.4912C>G p.L1638V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.681); catalogued as COSV60782876; called by muse, mutect2, varscan2
- TPTE2 | c.1343T>C p.V448A (on ENST00000400230 / NM_199254.2; = p.V371A on NM_130785.3) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV55018143; called by muse, varscan2
- TRDN | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV62117204; called by muse, mutect2, varscan2
- TRIM67 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV64158483; called by muse, mutect2, varscan2
- TSC2 | c.4958C>T p.S1653F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs45517383, CM040809, COSV51913245; ClinVar: not provided; called by muse, mutect2, varscan2
- TTC8 | c.1411C>T p.Q471* (on ENST00000338104 / NM_001288781.1; = p.Q455* on NM_144596.4) | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as CM155016, COSV57627013; called by muse, mutect2, varscan2
- TTF2 | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.197); catalogued as COSV65632272; called by muse, mutect2, varscan2
- TTN | c.56401G>A p.E18801K (on ENST00000591111; = p.E11377K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | PolyPhen possibly damaging (0.736); catalogued as rs751412533, COSV59957222; called by muse, mutect2, varscan2
- UBC | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV60058597, COSV60058883, COSV60060651; called by muse, mutect2, varscan2
- UBE2J2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs755105629, COSV59571961; called by muse, mutect2, varscan2
- UGT2A3 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV52359436; called by muse, mutect2, varscan2
- UGT2B11 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV71423167; called by muse, mutect2, varscan2
- UGT3A1 | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as COSV57096851, COSV57100392; called by muse, mutect2, varscan2
- UPF1 | c.1627G>A p.E543K (on ENST00000599848 / NM_001297549.2; = p.E532K on NM_002911.4) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV53194699; called by muse, mutect2, varscan2
- UPF2 | c.3807G>A p.G1269= | Splice Region (SNP) | VAF 5/36 reads (14%) | catalogued as COSV62659393; called by muse, varscan2
- UPF2 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV62659404; called by muse, varscan2
- UPF2 | c.2932G>C p.D978H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100706963, COSV62659414; called by muse, mutect2, varscan2
- USP32 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV56266053; called by muse, mutect2, varscan2
- USP6NL | c.992T>A p.F331Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV53210121; called by muse, mutect2, varscan2
- USPL1 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV54999200; called by muse, mutect2, varscan2
- UTP20 | c.7355T>G p.I2452S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV55374452; called by muse, mutect2
- VGLL4 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56075641; called by muse, mutect2, varscan2
- VPS4A | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54750194, COSV54750421; called by muse, mutect2, varscan2
- WDR45 | c.927C>G p.I309M (on ENST00000376372 / NM_001029896.2; = p.I310M on NM_007075.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV59875732; called by muse, mutect2, varscan2
- WDR48 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV56530997; called by muse, mutect2, varscan2
- WDR7 | c.3948G>C p.K1316N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54350341; called by muse, mutect2, varscan2
- WIZ | c.2594C>G p.S865C (on ENST00000673675 / NM_001371589.1; = p.S128C on NM_021241.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54606180; called by muse, mutect2, varscan2
- YBX3 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs140201332, COSV54384946; called by muse, mutect2, varscan2
- YEATS2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV59363572; called by muse, mutect2, varscan2
- YTHDC2 | c.3439C>T p.Q1147* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV50738637; called by muse, mutect2, varscan2
- ZBTB5 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV57039358; called by muse, mutect2, varscan2
- ZC3H12C | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53706748, COSV53707432; called by muse, mutect2, varscan2
- ZDHHC23 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as rs1023189075, COSV57629060; called by muse, mutect2, varscan2
- ZDHHC5 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV54705796; called by muse, mutect2, varscan2
- ZNF169 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1224816960, COSV61763633; called by muse, mutect2, varscan2
- ZNF544 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV54135029; called by muse, mutect2, varscan2
- ZNF786 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV60275458; called by muse, mutect2, varscan2
- ZNF8 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV52186915, COSV52188538; called by muse, mutect2, varscan2
- ZNF91 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV56082355; called by muse, mutect2, varscan2
- ZP2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as COSV54813102; called by muse, mutect2, varscan2
- ZRANB2 | c.57-1G>A p.X19_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV54671159, COSV54671278; called by muse, mutect2, varscan2
- ZSWIM4 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV54320289; called by muse, mutect2, varscan2
- CNTNAP4 | c.44T>C p.L15S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC2 | c.4075G>A p.V1359I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TADA2A | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.135); called by mutect2, varscan2
- ZFHX4 | c.562T>A p.Y188N | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- ACVR1B | c.1512G>A p.K504= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV57775943; called by muse, mutect2, varscan2
- ADAM12 | c.1266C>T p.F422= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs973553905, COSV100900603; called by muse, mutect2, varscan2
- ADAMTSL2 | c.627C>T p.D209= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs143046395; called by mutect2, varscan2
- ADD2 | c.2127C>T p.F709= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1230064180, COSV52457390, COSV52473837; called by muse, mutect2, varscan2
- AGAP4 | c.813G>A p.G271= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as rs1468269973; called by muse, mutect2
- ANKRD13C | c.102C>T p.L34= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52030664; called by muse, mutect2, varscan2
- ANKRD40 | c.126C>G p.V42= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV53333040; called by muse, mutect2, varscan2
- ANO2 | c.1041C>T p.L347= (on ENST00000356134 / NM_001278597.3; = p.L351= on NM_001278596.3) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV59013830; called by muse, mutect2
- APH1A | c.690C>T p.I230= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV52528611, COSV52530429; called by muse, mutect2, varscan2
- ARHGEF12 | c.3807G>A p.L1269= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV63103424; called by muse, mutect2, varscan2
- ARL6IP1 | c.585C>G p.L195= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV58614206; called by muse, mutect2, varscan2
- ASMTL | c.1578C>A p.I526= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV67243271; called by muse, mutect2, varscan2
- ATP5F1C | c.591G>A p.K197= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV59621248; called by muse, mutect2, varscan2
- B3GNTL1 | c.369G>A p.V123= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV57948005; called by muse, mutect2, varscan2
- BEND2 | c.2292C>T p.D764= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs367620811, COSV66220307; called by muse, mutect2, varscan2
- C5orf34 | c.312G>A p.V104= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV60929307; called by muse, mutect2, varscan2
- CACNA1I | c.4689C>G p.V1563= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV60803860; called by muse, mutect2, varscan2
- CAPRIN2 | c.2793A>T p.A931= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV51831566; called by muse, mutect2, varscan2
- CCNE1 | c.1218G>T p.G406= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV52903908; called by muse, mutect2, varscan2
- CCR7 | c.597C>G p.L199= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV55848885; called by muse, mutect2, varscan2
- CFAP91 | c.657C>T p.L219= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV56340019; called by muse, mutect2, varscan2
- CIC | c.165G>A p.P55= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs186431081, COSV99359632; called by muse, mutect2, varscan2
- CIT | c.2922C>T p.L974= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs150564429; called by muse, mutect2, varscan2
- CLPTM1 | c.1293C>G p.L431= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV61611511; called by muse, mutect2, varscan2
- DACT1 | c.1665C>T p.V555= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs765807517, COSV60020015; called by muse, mutect2, varscan2
- DBNDD2 | c.429G>A p.Q143= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1304842464, COSV100619551; called by muse, mutect2, varscan2
- DBNL | c.1209G>C p.V403= (on ENST00000448521 / NM_001014436.3; = p.V404= on NM_014063.7) | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99803712; called by muse, mutect2, varscan2
- DCHS1 | c.4971C>G p.L1657= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100202377, COSV55032924; called by muse, mutect2, varscan2
- DDX42 | c.2091G>A p.T697= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs370567643; called by muse, mutect2, varscan2
- ENPP6 | c.379C>T p.L127= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV57066881, COSV99698572; called by muse, mutect2, varscan2
- ESYT3 | c.2526G>A p.V842= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV67440554; called by muse, mutect2, varscan2
- FAH | c.909G>A p.L303= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV55720207; called by muse, mutect2, varscan2
- FAM47C | c.576G>A p.E192= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1556331664, COSV63725191; called by muse, mutect2, varscan2
- FBXL16 | c.1386C>T p.P462= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV50196696, COSV99556280; called by muse, mutect2, varscan2
- FEN1 | c.501G>A p.V167= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1439652731, COSV57250618; called by muse, mutect2, varscan2
- FKBP9 | c.1176C>G p.L392= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV99639817; called by muse, mutect2
- FLNC | c.543C>T p.F181= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV57953004; called by muse, mutect2, varscan2
- FLRT2 | c.1665G>A p.L555= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs887573930, COSV58138600, COSV58152351; called by muse, mutect2
- GAS2L2 | c.1965C>T p.I655= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- GCNT3 | c.1155C>T p.I385= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs773992456, COSV68532042; called by muse, mutect2, varscan2
- GOLGB1 | c.9675C>G p.V3225= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV58855190; called by muse, varscan2
- GRIK5 | c.1506C>T p.I502= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1568895472, COSV53476538; called by muse, mutect2, varscan2
- GTF3C1 | c.4905G>A p.V1635= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs11551766, COSV62239884; called by muse, mutect2, varscan2
- HIPK4 | c.126C>G p.L42= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV52519958; called by muse, mutect2, varscan2
- HMGB1 | c.237C>T p.I79= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1171559344, COSV58104394; ClinVar: likely benign; called by muse, mutect2
- HNF1A | c.1866C>T p.I622= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV56566678, COSV56568658; called by muse, mutect2, varscan2
- IL1R2 | c.495G>A p.V165= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV60206477; called by muse, mutect2, varscan2
- ITSN2 | c.1374T>C p.R458= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV61945103; called by muse, mutect2, varscan2
- KDM5B | c.3534C>T p.I1178= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV52505982; called by muse, mutect2, varscan2
- KLHL14 | c.33C>T p.F11= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV63831632; called by muse, mutect2, varscan2
- KMT2D | c.4476G>A p.Q1492= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV56423426; called by muse, mutect2, varscan2
- LCA5L | c.1677C>T p.L559= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs749303465, COSV55744524; called by muse, mutect2, varscan2
- LIPK | c.573G>A p.K191= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV68200705, COSV68200801; called by muse, mutect2, varscan2
- MAP1A | c.7344C>T p.L2448= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV55807365; called by muse, mutect2, varscan2
- MAST3 | c.1065C>T p.V355= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs377695566; called by mutect2, varscan2
- MAU2 | c.630C>G p.L210= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV53234394; called by muse, mutect2, varscan2
- MED13 | c.5196G>A p.V1732= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV67262660; called by muse, mutect2, varscan2
- MRAP2 | c.168C>T p.F56= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs150284745, COSV57631623; called by muse, mutect2, varscan2
- NOL11 | c.45G>C p.L15= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV53522681; called by muse, mutect2, varscan2
- NOTCH2 | c.5463G>C p.V1821= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV56686712; called by muse, mutect2, varscan2
- NTRK3 | c.564C>T p.Y188= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1003166835, COSV58115062; called by muse, mutect2, varscan2
- OR10X1 | c.231C>G p.L77= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV63767141; called by muse, mutect2, varscan2
- P2RY1 | c.945C>T p.L315= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100521701; called by muse, mutect2, varscan2
- PARP9 | c.894G>A p.K298= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV64450311, COSV64450809; called by muse, mutect2, varscan2
- PCDH12 | c.928C>T p.L310= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV51520305; called by muse, mutect2, varscan2
- PCNX3 | c.3681C>T p.L1227= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV63135719; called by muse, mutect2, varscan2
- PMS2 | c.2217G>A p.L739= | Silent (SNP) | VAF 25/30 reads (83%) | catalogued as rs752718686, COSV56220597; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRDM16 | c.2754G>A p.S918= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1319181975, COSV54585195; ClinVar: likely benign; called by muse, mutect2, varscan2
- PROS1 | c.370C>T p.L124= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV62398075; called by muse, mutect2
- PTPRT | c.2247C>T p.G749= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs763598762, COSV61970292; called by muse, mutect2, varscan2
- PUM1 | c.834G>A p.K278= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs1249484975, COSV99928117; called by muse, mutect2, varscan2
- RARRES1 | c.486C>T p.Y162= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs1328680365, COSV52961907; called by mutect2, varscan2
- RBP7 | c.404G>A p.*135= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53812711; called by muse, mutect2, varscan2
- RELA | c.366G>A p.K122= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV100425846; called by muse, mutect2
- RRS1 | c.1092G>A p.R364= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs747913909, COSV52554118; called by mutect2, varscan2
- RYR2 | c.11214G>A p.E3738= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV63674412; called by muse, mutect2, varscan2
- SAMD1 | c.807G>A p.E269= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV54114922; called by muse, mutect2, varscan2
- SDC4 | c.273G>A p.E91= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV65595257; called by muse, mutect2, varscan2
- SERPINA7 | c.720G>A p.Q240= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV59664796; called by muse, mutect2, varscan2
- SF3B3 | c.1968G>A p.E656= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV56786180; called by muse, varscan2
- SH3PXD2B | c.1309C>T p.L437= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV61125689; called by muse, mutect2, varscan2
- SLC25A42 | c.231C>G p.L77= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV59379844; called by muse, mutect2, varscan2
- SLC30A10 | c.714C>T p.I238= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV63070783; called by muse, mutect2
- SMARCD3 | c.1293C>G p.L431= (on ENST00000262188 / NM_001003801.2; = p.L418= on NM_003078.4) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV50389811; called by muse, mutect2, varscan2
- SPEF2 | c.4500G>A p.L1500= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV57428116; called by muse, mutect2, varscan2
- TARBP1 | c.4518G>A p.Q1506= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV50181132; called by muse, mutect2, varscan2
- TFR2 | c.2187C>T p.F729= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1476342623, COSV56153558, COSV56155710; called by muse, mutect2, varscan2
- THRAP3 | c.1851T>G p.A617= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV63567160; called by muse, mutect2, varscan2
- TMEM176A | c.390C>T p.I130= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs867362308, COSV50240556; called by muse, mutect2, varscan2
- TMEM54 | c.561G>C p.L187= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV61275656; called by muse, mutect2, varscan2
- TNK2 | c.798C>G p.V266= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100361377; called by muse, mutect2, varscan2
- TRHDE | c.2652G>A p.E884= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV53838093; called by muse, mutect2, varscan2
- TRIM45 | c.390C>T p.G130= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV56712913; called by muse, mutect2, varscan2
- TTC16 | c.324C>G p.L108= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV58852414; called by muse, mutect2, varscan2
- UMOD | c.1770G>A p.G590= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV56774526; called by muse, mutect2, varscan2
- VTN | c.666C>T p.F222= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV56873101; called by muse, mutect2, varscan2
- WFIKKN1 | c.1410C>T p.L470= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV50193121; called by muse, mutect2, varscan2
- XPO7 | c.1776C>T p.F592= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV53012767; called by muse, mutect2, varscan2
- YIF1B | c.63G>A p.S21= (on ENST00000339413 / NM_001039673.3; = p.S6= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs376897218; called by muse, mutect2, varscan2
- YKT6 | c.285G>A p.E95= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV56272121; called by muse, mutect2, varscan2
- ZFC3H1 | c.4095C>G p.L1365= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV66431225; called by muse, mutect2, varscan2
- ZHX1 | c.366G>C p.L122= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV52875939; called by muse, mutect2
- ZNF202 | c.225G>A p.L75= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV60246760; called by muse, mutect2, varscan2
- ZNF414 | c.435C>T p.F145= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ZNF579 | c.1500C>T p.L500= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV57637531; called by muse, mutect2, varscan2
- ZNF594 | c.1506C>G p.L502= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV68384960; called by muse, mutect2, varscan2
- AC244258.1 | n.782G>A | RNA (SNP) | VAF 6/31 reads (19%) | catalogued as rs745420112; called by muse, mutect2, varscan2
- ATAD3B | c.*256G>A | 3'UTR (SNP) | VAF 13/92 reads (14%) | catalogued as COSV58019900; called by muse, mutect2, varscan2
- CREM | c.891-360C>T | Intron (SNP) | VAF 14/51 reads (27%) | catalogued as rs371182851; called by muse, mutect2, varscan2
- FOLH1B | n.1783C>G | RNA (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- LRP5L | n.128G>A | RNA (SNP) | VAF 14/59 reads (24%) | catalogued as rs756148751, COSV68602009; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2239G>A | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54095099; called by muse, mutect2, varscan2
- SNX29P2 | n.847G>C | RNA (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- TMPRSS3 | chr21:42396073 G>A | 5'Flank (SNP) | VAF 15/44 reads (34%) | catalogued as rs767574751, COSV52301358, COSV52302828; called by muse, mutect2, varscan2
- TRAPPC9 | chr8:140458370 G>A | 5'Flank (SNP) | VAF 10/56 reads (18%) | catalogued as rs766527036, COSV66895575; called by muse, mutect2, varscan2
- XPO5 | c.*1154G>A | 3'UTR (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99540970; called by muse, mutect2, varscan2
- ZNF99 | c.*1005C>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | catalogued as COSV68055271; called by muse, mutect2, varscan2
